Surgical pathology report (de-identified scan), TCGA case TCGA-BT-A3PH, project TCGA-BLCA (Bladder Urothelial Carcinoma), tissue source site University of Pittsburgh, specimen TCGA-BT-A3PH-01A (Primary Tumor).

Collection Date:

FINAL DIAGNOSIS:

PART 1:

URETER, RIGHT DISTAL MARGIN, BIOPSY -

- A. SEGMENT OF URETER LINED BY BENIGN UROTHELIAL MUCOSA.
- B. NO UROTHELIAL CARCINOMA IN SITU (CIS) NOR INVASIVE UROTHELIAL CARCINOMA SEEN.

PART 2:

URETER, LEFT DISTAL MARGIN, BIOPSY -

- A. SEGMENT OF URETER LINED BY BENIGN UROTHELIAL MUCOSA.
- B. NO UROTHELIAL CARCINOMA IN SITU (CIS) NOR INVASIVE UROTHELIAL CARCINOMA SEEN.

PART 3:

URINARY BLADDER, DISTAL URETERS, PROSTATE, BILATERAL SEMINAL VESICLES, AND BILATERAL DISTAL VASA DEFERENTIA, RADICAL CYSTOPROSTATECTOMY -

URINARY BLADDER:

- A. ULCERATED INVASIVE, UROTHELIAL CARCINOMA, HIGH-GRADE (2004 WHO/ISUP), INVOLVING MOST OF THE URINARY BLADDER, INCLUDING THE TRIGONE, BILATERAL URETERAL OSTIA, ANTERIOR AND POSTERIOR WALLS, AND RIGHT AND LEFT LATERAL WALLS.
- B. MAXIMAL TUMOR DIMENSION IS 10 CM.
- C. CARCINOMA INVADES THROUGH THE DETRUSOR MUSCLE AND GROSSLY EXTENDS INTO PERIVESICAL ADIPOSE TISSUE.
- D. RARE PERINEURAL INVASION IS IDENTIFIED (SLIDE 3P).
- E. NUMEROUS LYMPHATIC TUMOR EMBOLI ARE IDENTIFIED (SLIDES 3E, 3L - 3Q).
- F. ALL SURGICAL RESECTION MARGINS ARE BENIGN.
- G. TNM PATHOLOGIC STAGE: pT3b N2 MX (See Synoptic).

PROSTATE AND BILATERAL SEMINAL VESICLES, RADICAL CYSTOPROSTATECTOMY:

- A. PROSTATIC TISSUE WITH MULTIPLE UROTHELIAL CARCINOMA LYMPHATIC TUMOR EMBOLI (SLIDES 3B, 3D, 3S-3X, 3Z), NODULAR HYPERPLASIA, PROSTATIC GLANDULAR ATROPHY, AND SMALL PROSTATIC CALCULI.
- B. BENIGN SEMINAL VESICLES.

PART 4:

URETER, RIGHT DISTAL, RESECTION -

- A. SEGMENT OF URETER LINED BY BENIGN UROTHELIAL MUCOSA.
- B. NO UROTHELIAL CARCINOMA IN SITU (CIS) NOR INVASIVE UROTHELIAL CARCINOMA SEEN.

PART 5:

LYMPH NODES, RIGHT PELVIC, EXCISION -

- A. METASTATIC UROTHELIAL CARCINOMA IS PRESENT IN SIX OF TWELVE LYMPH NODES (6/12) AND IN THE RIGHT PELVIC ADIPOSE TISSUE.
- B. LARGEST METASTATIC FOCUS MEASURES 4 CM (SLIDES 5A).

PART 6:

LYMPH NODES, LEFT PELVIC, EXCISION -

- A. METASTATIC UROTHELIAL CARCINOMA IS PRESENT IN TWO OF FIVE LYMPH NODES (2/5).
- B. LARGEST METASTATIC FOCUS MEASURES 2.3 CM.
- C. NO EXTRACAPSULAR EXTENSION.

PART 7:

"LYMPH NODE", MESENTERIC, EXCISION -

- A. BENIGN FIBROADIPOSE TISSUE WITH ORGANIZING FAT NECROSIS.
- B. NO LYMPH NODE TISSUE PRESENT.
- C. NO EVIDENCE OF MALIGNANCY.

CASE SYNOPSIS:

SYNOPTIC DATA - PRIMARY URINARY BLADDER TUMORS

SPECIMEN TYPE:

Radical cystoprostatectomy

TUMOR SITE:

Trigone, Right lateral wall, Left lateral wall, Anterior wall, Posterior wall

TUMOR SIZE:

Greatest dimension: 10 cm

Additional dimensions: 6 X 2.9 cm

HISTOLOGIC TYPE:

Urothelial (transitional cell) carcinoma

ASSOCIATED EPITHELIAL LESIONS:

None identified

HISTOLOGIC GRADE:

Urothelial carcinoma - High-grade

TUMOR CONFIGURATION:

Solid/nodule, Ulcerated

PATHOLOGIC STAGING (pTNM):

pT3b

pN2

Number of nodes examined: 17

Number of nodes involved: 8

pMX

MARGINS:

Margins uninvolved by invasive carcinoma

VENOUS/LYMPHATIC (LARGE/SMALL) VESSEL INVASION (V/L):

Present

DIRECT EXTENSION OF INVASIVE TUMOR:

Perivesical fat

ICD-O-3
carcinoma, urothelial
8120/3
site: bladder, NOS
C67.9

Source: NCI Genomic Data Commons file fa43693d-26d3-4e81-a847-cd472d48747b (TCGA-BT-A3PH.25DF244E-6548-4304-A720-4CC31BDCB305.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).